HCMI case HCM-EXPT-1041-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/6816430e-41fe-4c8b-b56d-125efc074b3a

Demographics
Sex at birth: female; Year of birth: 1934.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.9; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Ileum; Classification of tumor: primary; Age at diagnosis: 83.1 years (30,342 days); Prior treatment: No.
   Recorded as not given: neoadjuvant treatment (type not reported).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-EXPT-1041-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-EXPT-1041-C18-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 6; Percent necrosis: 2; Percent stromal cells: 32; Percent lymphocyte infiltration: 33; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
  Slide HCM-EXPT-1041-C18-01A-01-S1-HE: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 70; Percent normal cells: 4; Percent necrosis: 1; Percent stromal cells: 65; Percent lymphocyte infiltration: 23; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
